Somatic mutation profile of tumor specimen MMRF_2601_1_BM_CD138pos (aliquot MMRF_2601_1_BM_CD138pos_T1_KHS5U_L13284) from MMRF case MMRF_2601, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.8 years (25,861 days).
Specimen MMRF_2601_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cfdfe50-7004-43a9-9fef-be7ebd51e495.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2601_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2601_1_PB_WBC_C3_KHS5U_L13285; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad43dcd2-8db9-4249-b74b-e7fe538e4377

The open-access MAF lists 86 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 25, Silent 13, Intron 9, 5'UTR 4, Frame Shift Del 3, 5'Flank 2, Nonsense Mutation 1, Nonstop Mutation 1, RNA 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs202120426, COSV58370863; ClinVar: uncertain significance; called by muse, mutect2
- DCC | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs145416326, COSV59128591; called by muse, mutect2, varscan2
- ERLIN2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs753779663; called by muse, mutect2, varscan2
- FAM83H | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1282297760, COSV62027344; called by muse, mutect2
- FKBP14 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51652329; called by muse, mutect2
- GPR158 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761950258, COSV66282915; called by muse, mutect2
- IGLV3-1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373323725; called by muse, varscan2
- LRP4 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV66136580; called by muse, mutect2, varscan2
- MYO5B | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs776347920; called by muse, mutect2, varscan2
- RAD1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 88/326 reads (27%) | catalogued as rs369979648; called by muse, mutect2, varscan2
- SETBP1 | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 85/147 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs1225303329, COSV104387888; called by muse, mutect2, varscan2
- SGSH | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1396883948; called by muse, mutect2, varscan2
- TRAF3 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61025109; called by muse, mutect2, varscan2
- TSPOAP1 | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as rs11652447, COSV99270111; called by muse, mutect2
- TTC3 | c.5080C>A p.L1694I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139272991; called by muse, mutect2, varscan2
- ASAH2 | c.864_873del p.D288Efs*17 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | called by mutect2, pindel, varscan2
- BCL2L2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CYP4B1 | c.1094A>C p.Y365S | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EQTN | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GEMIN4 | c.2589G>C p.W863C | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAD | c.3374T>G p.L1125R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRAS | c.29_31dup p.G10dup | In Frame Ins (INS) | VAF 20/224 reads (9%) | called by mutect2, pindel
- PTPN13 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2
- ROCK2 | c.1990A>C p.K664Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RPL37 | c.293A>C p.*98Sext*9 | Nonstop Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- SNX2 | c.385del p.E129Kfs*14 | Frame Shift Del (DEL) | VAF 52/191 reads (27%) | called by mutect2, pindel
- STIL | c.1592del p.S531Ffs*23 | Frame Shift Del (DEL) | VAF 77/197 reads (39%) | called by mutect2, pindel, varscan2
- TLL1 | c.1168A>C p.N390H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB20 | c.2018A>G p.H673R (on ENST00000474710 / NM_001164342.2; = p.H600R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF569 | c.1094A>C p.Q365P | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF865 | c.639C>A p.F213L | Missense Mutation (SNP) | VAF 131/190 reads (69%) | SIFT tolerated (0.19); called by muse, mutect2, varscan2
- AFDN | c.4539C>T p.P1513= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs767998358; called by muse, mutect2, varscan2
- APCDD1L | c.885C>A p.V295= | Silent (SNP) | VAF 26/48 reads (54%) | called by muse, varscan2
- CAPN15 | c.252C>T p.N84= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as rs772660924; called by muse, mutect2, varscan2
- COL22A1 | c.3708C>T p.P1236= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs201986505; called by muse, mutect2, varscan2
- CSMD1 | c.546C>T p.I182= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101225334, COSV68190600; called by muse, mutect2, varscan2
- DSCAML1 | c.5775C>T p.G1925= (on ENST00000321322; = p.G1865= on NM_020693.4) | Silent (SNP) | VAF 84/201 reads (42%) | catalogued as rs770130757; called by muse, mutect2, varscan2
- FAM131B | c.126G>A p.K42= | Silent (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- GSG1L2 | c.663G>A p.S221= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as rs1042210403; called by muse, mutect2
- HERPUD1 | c.330T>A p.G110= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- KIAA1210 | c.4458G>T p.S1486= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV68175880; called by muse, mutect2, varscan2
- MUC16 | c.10813A>C p.R3605= | Silent (SNP) | VAF 79/345 reads (23%) | called by muse, mutect2, varscan2
- SLC38A4 | c.849G>C p.V283= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- UNC80 | c.7407G>A p.L2469= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as COSV55888613; called by muse, mutect2, varscan2
- ACVRL1 | c.*1578C>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- AHRR | c.*2612C>T | 3'UTR (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*776_*790delinsA | 3'UTR (DEL) | VAF 24/84 reads (29%) | called by pindel, varscan2*
- BCL7A | chr12:122021474 C>G | 5'Flank (SNP) | VAF 42/96 reads (44%) | called by muse, varscan2
- BCL7A | chr12:122021531 T>C | 5'Flank (SNP) | VAF 37/95 reads (39%) | called by muse, varscan2
- COQ10A | c.*45C>A | 3'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100370068; called by muse, mutect2, varscan2
- CXCR1 | c.*407G>T | 3'UTR (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- DNAH17 | c.5191-207C>T | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- DTX1 | c.-450A>T | 5'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- FNDC5 | c.*1444T>C | 3'UTR (SNP) | VAF 88/171 reads (51%) | called by muse, mutect2, varscan2
- GAB2 | c.*2549A>G | 3'UTR (SNP) | VAF 81/176 reads (46%) | catalogued as rs766598059; called by muse, mutect2, varscan2
- GATAD2B | c.*82T>C | 3'UTR (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- GRIN2A | c.*8428T>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | catalogued as rs1567267468; called by muse, mutect2, varscan2
- GRK5 | c.*152G>A | 3'UTR (SNP) | VAF 21/260 reads (8%) | catalogued as rs1219701095; called by muse, mutect2
- HEY2 | c.*670C>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as rs1197130041; called by muse, mutect2
- LRPAP1 | c.205-78C>A | Intron (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- LTB | c.163-77C>G | Intron (SNP) | VAF 170/409 reads (42%) | catalogued as rs576331800, COSV53002587; called by muse, varscan2
- LTB | c.163-144C>G | Intron (SNP) | VAF 84/196 reads (43%) | catalogued as rs534971843; called by muse, varscan2
- MAB21L2 | c.*34G>A | 3'UTR (SNP) | VAF 11/338 reads (3%) | called by muse, mutect2
- MCMDC2 | c.*176A>C | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- MFSD13A | c.*680_*688del | 3'UTR (DEL) | VAF 29/68 reads (43%) | called by mutect2, pindel, varscan2
- MFSD14C | n.489C>T | RNA (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- MRPL30 | c.*1453C>G | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- NCKAP5L | c.*20G>A | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- PDE3B | c.*531C>G | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- PDE6H | c.*28G>A | 3'UTR (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- PHKA2 | c.-80A>T | 5'UTR (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- POGZ | c.2433-16C>G | Intron (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*1077T>C | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- PRDM7 | chr16:90057745 C>T | 3'Flank (SNP) | VAF 8/164 reads (5%) | catalogued as rs1261588172; called by muse, mutect2
- RAB20 | c.*461T>G | 3'UTR (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.-26C>T | 5'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- STAC2 | c.*258G>C | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- TAF7 | c.-662C>T | 5'UTR (SNP) | VAF 127/217 reads (59%) | catalogued as COSV100514985; called by muse, mutect2, varscan2
- TLX1 | c.*253T>C | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- TMEM128 | c.97+131G>C | Intron (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- TMEM170B | c.*3228A>G | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- UBA3 | c.1083+66A>G | Intron (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- VSTM2L | c.*904C>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- XPR1 | c.*5036A>G | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- ZNF451 | c.186+10055G>A | Intron (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- ZNF707 | c.15+18C>A | Intron (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
